Gene-level copy-number profile of tumor specimen TCGA-EE-A29V-06A from TCGA case TCGA-EE-A29V, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 87.1 years (31,805 days).
Specimen TCGA-EE-A29V-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.13d39f30-6ffb-4203-902f-2e555fa4582e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A29V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c01fb77-28ed-480b-974e-a642e0d0835d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 16,847; copy number 2: 38,072; copy number 3: 4,418; copy number 4: 39; copy number 5: 274; copy number 6: 134.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A29V-06A-12D-A191-01): tumor purity 0.71, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:8,548,361–9,135,591, 27 genes: AC092746.1, Y_RNA, AC092184.1, AICDA, AC092184.2, HADHAP2, MFAP5, AC092490.2, AC092490.3, RIMKLB, RPSAP51, A2ML1-AS1, AC092490.1, A2ML1-AS2, A2ML1, AC006581.2, PHC1, M6PR, KLRG1, AC006581.1, HNRNPA1P34, VDAC2P2, LINC00612, A2M-AS1, A2M, KRT17P8, BTG1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 408 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,979,014–73,715,214, 5 genes, copy number 5 (within-gene range 2–5): AL732618.1, KRT8P21, RN7SKP19, LINC01360, LINC02238.
- chr1:114,468,315–115,931,616, 33 genes, copy number 6: EIF2S2P5, Y_RNA, PKMP1, BCAS2, DENND2C, AMPD1, RN7SL432P, NRAS, CSDE1, RNY1P13, SIKE1, NR1H5P, SYCP1, TSHB, TSPAN2, LINC01765, AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1, VANGL1, CASQ2, NHLH2, HNRNPA1P43, LINC01649, AL357137.1.
- chr1:117,111,060–121,580,524, 100 genes, copy number 6 (broad region; genes not listed).
- chr5:16,033,229–16,681,905, 12 genes, copy number 5: RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1, AC024588.1, AC022113.1, Y_RNA.
- chr8:50,762,460–54,479,963, 57 genes, copy number 5: CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7.
- chr8:54,522,799–54,523,297, 1 gene, copy number 5: SEC11B.
- chr8:55,067,585–61,714,640, 100 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:61,909,984–61,910,802, 1 gene, copy number 6: C1GALT1P3.
- chr8:62,248,591–63,014,000, 1 gene, copy number 5 (within-gene range 2–5): NKAIN3.
- chr8:62,658,343–67,849,338, 84 genes, copy number 5 (broad region; genes not listed).
- chr8:76,162,119–77,014,028, 14 genes, copy number 5: AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18.

Autosomal genes at a single copy (total copy number 1): 14,460. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
